Gene-level copy-number profile of tumor specimen C3L-00096-01 from CPTAC case C3L-00096, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 52.5 years (19,180 days).
Specimen C3L-00096-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cbc7ca44-f64a-465a-a891-e39f338e4eb7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00096-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/32a82ee8-1a25-404d-8a6b-b9103c08f66d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 24,225; copy number 2: 30,105; copy number 3: 3,103; copy number 4: 2; copy number 5: 1,457.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:241,881,363–242,084,233, 7 genes (within-gene range 0–1): LINC01237, FAM240C, LINC01238, AC093642.3, AC093642.1, AC093642.6, LINC01880.
- chr4:68,537,184–68,670,652, 5 genes (within-gene range 0–1): UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr5:1,725,149–1,728,172, 1 gene: AC112176.1.
- chr13:68,634,190–69,408,735, 9 genes: RPS3AP52, RPL12P34, RN7SL761P, LINC00550, LINC02342, ZDHHC20P4, SNRPFP3, LINC00383, SRSF1P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,457 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:47,773,111–114,791,929, 965 genes, copy number 5 (broad region; genes not listed).
- chr8:115,950,511–145,066,685, 492 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 21,369. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
